Gene-level copy-number profile of tumor specimen ALCH-B4Q6-TTP1-A from ALCHEMIST case ALCH-B4Q6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 78.1 years (28,541 days).
Specimen ALCH-B4Q6-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1e6cde49-3329-4cc6-89a1-2f6352c16be3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4Q6-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,875 have no estimate.
https://portal.gdc.cancer.gov/files/b2ebac69-a20e-417b-9d3f-ab64e6feb9cf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 265; copy number 1: 10,985; copy number 2: 46,270; copy number 3: 1,164; copy number 4: 11; copy number 5: 2; copy number 6: 46; copy number 7: 1; copy number 8: 1; copy number 10: 3.

Homozygous deletions (total copy number 0; autosomes only): 242 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–143,739,506, 8 genes: AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2.
- chr1:143,811,359–143,846,504, 2 genes: AC239798.1, AC239798.2.
- chr1:143,929,994–143,930,382, 1 gene (within-gene range 0–1): RPL22P5.
- chr2:89,252,211–91,714,745, 58 genes: IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, 5S_rRNA, IGKV2D-40, IGKV1D-39, IGKV2D-38, IGKV1D-37, IGKV2D-36, IGKV1D-35, IGKV3D-34, IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1, LSP1P4, RNA5SP100, DRD5P1, AC027612.2.
- chr3:90,202,316–90,261,708, 2 genes: PROS2P, HSPE1P19.
- chr3:147,386,046–147,406,809, 2 genes (within-gene range 0–2): ZIC4, ZIC4-AS1.
- chr4:9,692,495–9,712,233, 3 genes: FAM86MP, ALG1L3P, Metazoa_SRP.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr6:27,652,602–27,713,352, 2 genes: RPL8P1, LINC01012.
- chr6:58,386,799–60,546,660, 2 genes: AL603755.1, AC244258.1.
- chr7:76,959,835–77,043,776, 10 genes (within-gene range 0–2): DTX2P1-UPK3BP1-PMS2P11, FDPSP7, AC114737.1, DTX2P1, UPK3BP1, PMS2P11, Y_RNA, SPDYE17, PMS2P9, Y_RNA.
- chr7:129,953,234–130,051,451, 4 genes (within-gene range 0–2): AC073320.1, Y_RNA, ZC3HC1, RNA5SP245.
- chr9:121,574,891–121,576,214, 1 gene (within-gene range 0–2): AL357936.1.
- chr10:38,783,004–42,281,819, 6 genes: AL590623.1, KSR1P1, IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8.
- chr10:44,488,335–44,488,445, 1 gene: AL356157.2.
- chr10:92,418,667–92,420,875, 1 gene: MARK2P9.
- chr11:48,880,111–48,908,946, 4 genes: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr11:50,246,554–54,725,816, 18 genes: PHKG1P3, AC109635.4, AC109635.2, AC109635.1, LINC02750, AC024405.2, AC024405.1, OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P.
- chr12:12,915,829–12,915,918, 1 gene (within-gene range 0–2): MIR614.
- chr14:18,333,726–18,699,978, 20 genes: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11, CR383656.3, RPL22P20, CR383656.4.
- chr14:21,563,819–21,580,076, 2 genes: RBBP4P5, OR10G3.
- chr16:2,939,714–2,954,276, 1 gene (within-gene range 0–2): AC004034.1.
- chr17:30,629,680–30,702,775, 2 genes (within-gene range 0–2): LRRC37BP1, RN7SL316P.
- chr17:30,724,982–30,740,275, 4 genes (within-gene range 0–1): AC127024.7, AC127024.3, AC127024.2, AC127024.8.
- chr17:39,404,285–39,451,272, 1 gene (within-gene range 0–2): MED1.
- chr19:24,146,701–24,163,425, 2 genes: AC073534.2, AC073534.1.
- chr19:48,993,562–49,108,605, 24 genes: RUVBL2, MIR6798, LHB, AC008687.4, CGB3, AC008687.1, NTF6A, NTF6G, CGB2, CGB1, NTF6B, AC008687.5, CGB5, CGB8, AC008687.6, CGB7, AC008687.8, AC008687.7, AC008687.2, NTF4, AC008687.3, KCNA7, RN7SL708P, SNRNP70.
- chr20:56,730,397–56,731,460, 1 gene: AL133232.1.
- chr21:7,744,962–9,368,775, 44 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2, CR381653.1, SNX18P12.
- chr21:10,328,411–13,016,692, 12 genes: AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1.
- chr21:13,047,583–13,047,689, 1 gene (within-gene range 0–2): RNU6-614P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 52 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,450,245, 3 genes, copy number 10: AC239859.5, RNA5SP533, AC239859.3.
- chr5:55,995,167–56,003,649, 2 genes, copy number 5: FLJ31104, AC016596.1.
- chr8:102,204,502–102,238,961, 1 gene, copy number 7: RRM2B.
- chr14:100,879,753–100,903,722, 1 gene, copy number 6 (within-gene range 2–6): RTL1.
- chr14:100,924,824–100,998,541, 45 genes, copy number 6: SNORD113-1, SNORD113-2, SNORD113-3, SNORD113-4, SNORD113-5, SNORD113-6, SNORD113-7, SNORD113-8, SNORD113-9, SNORD114-1, SNORD114-2, SNORD114-3, SNORD114-4, SNORD114-5, AL132709.1, SNORD114-6, SNORD114-7, SNORD114-9, SNORD114-10, SNORD114-11, SNORD114-12, SNORD114-13, SNORD114-14, SNORD114-15, SNORD114-16, SNORD114-17, SNORD114-18, SNORD114-19, AL132709.3, AL132709.2, AL132709.4, SNORD114-20, SNORD114-21, SNORD114-22, SNORD114-23, SNORD114-24, SNORD114-25, SNORD114-26, SNORD114-27, SNORD114-28, SNORD114-29, SNORD114-30, SNORD114-31, AL132709.5, AL132709.6.

Autosomal genes at a single copy (total copy number 1): 8,321. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
